Somatic mutation profile of tumor specimen 0E1HF8 from CCDI case PBCWKJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1HF8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3318ba4-2cc7-4148-a284-69b0454de268.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e785dad-306e-429f-82f4-336cc33f7a7b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HKDC1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 60/946 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200115968; called by muse, mutect2
- TNC | c.1431C>A p.H477Q | Missense Mutation (SNP) | VAF 54/820 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.063); called by muse, mutect2
- ZNF586 | c.600C>G p.H200Q | Missense Mutation (SNP) | VAF 71/1470 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGAP6 | c.1656A>T p.L552= | Silent (SNP) | VAF 66/978 reads (7%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 36/1094 reads (3%) | called by muse, mutect2
